Somatic mutation profile of tumor specimen BA2261D (aliquot aq-BA2261D) from BEATAML1.0 case 2528, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: female; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia with myelodysplasia-related changes; Tissue or organ of origin: Bone marrow; Age at diagnosis: 62.8 years (22,929 days).
Specimen BA2261D: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b71b318e-3309-4fd2-81c5-3fc017088a6e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA2345D (Solid Tissue Normal), aliquot aq-BA2345D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3c7ef405-ce0d-4652-afe9-dd17c73497b1

The open-access MAF lists 18 somatic variants for this specimen: 12 protein-altering or splice-affecting, 2 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 10, Intron 3, Silent 2, Frame Shift Del 1, 3'UTR 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADAMTS12 | c.1400C>T p.A467V | Missense Mutation (SNP) | VAF 53/122 reads (43%) | SIFT tolerated (0.12); PolyPhen benign (0.358); catalogued as rs896943160; called by muse, mutect2, varscan2
- CACNG3 | c.241G>A p.D81N | Missense Mutation (SNP) | VAF 52/122 reads (43%) | SIFT tolerated (1); PolyPhen probably damaging (0.99); catalogued as rs750272065, COSV50067133, COSV50080122; called by muse, mutect2, varscan2
- CFP | c.1244+1G>A p.X415_splice | Splice Site (SNP) | VAF 48/125 reads (38%) | catalogued as rs1178102878; called by muse, mutect2, varscan2
- DSCAM | c.2732G>A p.G911E | Missense Mutation (SNP) | VAF 244/322 reads (76%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV68037429; called by muse, varscan2
- RELN | c.208C>T p.P70S | Missense Mutation (SNP) | VAF 15/76 reads (20%) | SIFT tolerated (0.05); PolyPhen benign (0.054); catalogued as rs773680003; called by muse, mutect2, varscan2
- CPXCR1 | c.859A>C p.T287P | Missense Mutation (SNP) | VAF 3/31 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.362); called by muse, mutect2
- FOXR2 | c.886C>A p.Q296K | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.721); called by muse, mutect2
- GCGR | c.58C>A p.Q20K | Missense Mutation (SNP) | VAF 3/49 reads (6%) | SIFT tolerated (0.19); PolyPhen benign (0.015); called by muse, mutect2
- KLK8 | c.160C>G p.Q54E | Missense Mutation (SNP) | VAF 27/80 reads (34%) | SIFT tolerated (0.93); PolyPhen benign (0); called by muse, varscan2
- MAPK4 | c.631G>T p.D211Y | Missense Mutation (SNP) | VAF 48/147 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TCIRG1 | c.2288del p.G763Afs*20 | Frame Shift Del (DEL) | VAF 16/133 reads (12%) | called by mutect2, varscan2
- ZNF85 | c.646A>G p.T216A | Missense Mutation (SNP) | VAF 57/129 reads (44%) | SIFT tolerated (0.4); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- WDFY4 | c.2427C>A p.R809= | Silent (SNP) | VAF 4/33 reads (12%) | called by muse, mutect2
- ZIK1 | c.369A>G p.P123= | Silent (SNP) | VAF 78/191 reads (41%) | called by muse, varscan2
- AKT2 | c.-84-9891C>T | Intron (SNP) | VAF 65/140 reads (46%) | catalogued as rs759358200; called by muse, mutect2, varscan2
- ALDH3A1 | c.*139G>T | 3'UTR (SNP) | VAF 3/31 reads (10%) | catalogued as rs930638393; called by muse, mutect2
- RCHY1 | c.327-53C>G | Intron (SNP) | VAF 103/239 reads (43%) | called by muse, mutect2, varscan2
- RPL10 | c.330-167C>T | Intron (SNP) | VAF 8/76 reads (11%) | catalogued as rs782020941; called by muse, mutect2
